Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AO, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AO-01A (Primary Tumor).

1CB-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Site Code: breast, NOS C50.9 12/21/10

Final diagnosis

Breast, left, wide local excision: Infiltrating ductal carcinoma, Nottingham grade III (of III) [tubules 3/3, nuclei 3/3, mitoses 2/3, Nottingham score 8/9], forming a 1.7 x 1.6 x 1.2 cm mass [AJCC pT1c]. Ductal carcinoma in situ, intermediate nuclear grade, comprising less than 5% of tumor volume. Angiolymphatic invasion is absent. Biopsy site changes present. All surgical resection margins, after re-excisions of the medial and superior margins, are negative for tumor (minimum tumor free margin, 0.9 cm, superior margin). A single intramammary lymph node, present at the medial margin, is positive for metastatic carcinoma. The involved lymph node measures 1.5 mm in maximum dimension.

Lymph nodes, left axillary sentinel, excision: A single (of 2) left axillary lymph node is positive for metastatic carcinoma [AJCC pN1]. Blue dye is identified in both left axillary sentinel lymph nodes. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Lymph nodes, left axillary, dissection: Multiple (36) left axillary lymph nodes are negative for tumor.

Faxitron done.

Estrogen and progesterone receptor analysis and Her-2/NEU have been ordered on paraffin embedded tissue.

Primary Malignancy History		☒

Source: NCI Genomic Data Commons file c31bcbbe-f1be-4597-ad2c-4996e8deab97 (TCGA-AR-A1AO.37EF1828-0A53-4358-97C7-A7849EC653AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).